TARGET case TARGET-15-SJMPAL043509 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a1a0b3ee-5612-4bf3-a7b5-72bcaa07591f

Demographics
Sex at birth: male; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.2 years (2,999 days); Year of diagnosis: 1998; Days to last follow up: 5,938 days (16.3 years).

Follow-up (1 entry)
- Days to follow up: 5,938 days (16.3 years); First event: Relapse; Year of follow up: 2015.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL043509-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 5938
- Protocol: St. Jude
- Initial Therapy: AML
- Karyotype: 46,XY,i(17)(q10)[1]/46,XX(Donor)[12]/46,XY[7]
- WHO ALAL Classification: T/M
- WHO Dx: AML
- WHO RL1: T/M
- WHO RL2: AML
